Somatic mutation profile of tumor specimen 1105226 (aliquot 7316UP-613-1105226) from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105226: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ee9ff50-9d9a-432f-bc15-fa5a1e3d0a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105214 (Blood Derived Normal), aliquot 7316UP-613-1105214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40b389c9-4535-42c9-be02-c74ecce1035f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 40/370 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 34/543 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2
- LSR | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- KLC2 | c.*328C>T | 3'UTR (SNP) | VAF 11/254 reads (4%) | catalogued as rs1224502861; called by muse, mutect2
